CCG case CUPP-B38L — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d45e4148-b10a-4c15-8f4a-7f5450098bf7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Year of birth: 1957; Vital status: Dead; Days to death: 230 days; Year of death: 2018; Cause of death: Cancer Related.

Diagnoses (2)
1. Adenocarcinoma, metastatic, NOS (the primary disease): ICD-O-3 morphology code: 8140/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Brain, NOS; Classification of tumor: metastasis; Age at diagnosis: 59.9 years (21,864 days); Year of diagnosis: 2017; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: TX; AJCC clinical M: M1; AJCC clinical stage: Stage III; AJCC pathologic T: TX; AJCC pathologic M: M1; AJCC pathologic stage: Stage III; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Brain, NOS.
   Pathology details: Consistent pathology review: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Timepoint category: First Treatment.
2. Recurrence of the brain (histology not recorded by GDC). Age at diagnosis: 60.2 years (21,986 days); Year of diagnosis: 2018; Days to diagnosis: 122 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease; Treatment outcome: Partial Response.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 100; ECOG performance status: 0.
- Day 122 (recurrence): Progression or recurrence: Yes; Progression or recurrence anatomic site: Brain, NOS; Days to recurrence: 122 days.
- Days to follow up: 230 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 65 kg; Height: 168 cm; BMI: 23.

Exposures
- Tobacco smoking status: Smoker at Diagnosis.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Head and Neck Cancer; Relationship sex at birth: male.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B38L-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Lymphocytes; Preservation method: Frozen.
- Sample CUPP-B38L-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B38L-TTM1-A-1-0-S1: Section location: Bottom; Percent tumor cells: 20; Percent tumor nuclei: 25; Percent normal cells: 35; Percent necrosis: 5; Percent stromal cells: 40; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
